Surgical pathology report (de-identified scan), TCGA case TCGA-N9-A4Q3, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MD Anderson, specimen TCGA-N9-A4Q3-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

ICD-0-3

Mixed Mullerian Tumor 8950/3

Site Path: Corpus Uteri, endometrium

CS# 1

CRCF: Uterus, NOS C55.9

copied AMS 1/16/13

- (A) SEGMENT UTERINE ARTERY:
Benign connective tissue and artery; no tumor present.
- (B) UTERUS, FALLOPIAN TUBES AND OVARIES:
MIXED MALIGNANT MULLERIAN TUMOR. (SEE COMMENT)
TUMOR ARISES IN ASSOCIATION WITH AN ENDOMETRIAL POLYP.
Myometrial invasion is not identified.
Lymphatic vascular invasion is not identified.
Cervix, no tumor present.
Adenomyosis.
Leiomyomata.
Bilateral ovaries and fallopian tubes, no tumor present.
Bilateral ovaries, endosalpingiosis and epithelial inclusion cysts.
- (C) LEFT PELVIC NODE:
Thirteen lymph nodes, no tumor present (0/13).
- (D) LEFT COMMON ILIAC SENTINEL LYMPH NODE:
One lymph node, no tumor present (0/1)
- (E) LEFT COMMON LYMPH NODE:
One lymph node, no tumor present (0/1).
- (F) RIGHT COMMON ILIAC LYMPH NODE:
One lymph node, no tumor present (0/1).
- (G) RIGHT PELVIC LYMPH NODE:
Seven lymph nodes, no tumor present (0/7).
- (H) PARAAORTIC LYMPH NODE:
Five lymph nodes, no tumor present (0/5).
- (I) OMENTAL BIOPSY:
No tumor present.

COMMENT

The tumor arises in association with endometrial polyp. It consists mainly of carcinomatous component (serous carcinoma and endometrioid carcinoma with papillary features) and a minor (20%) sarcomatous component, which is a high-grade unclassified sarcoma without heterologous elements.

GROSS DESCRIPTION

- (A) SEGMENT UTERINE ARTERY - A segment of vascular tissue measuring 1.1 cm in length and 0.5 cm in diameter and specimen is sectioned and reveal no lesion grossly seen. A cross section and longitudinal section of the specimen is submitted in A.
- (B) UTERUS, FALLOPIAN TUBES AND OVARIES - An 8.5 x 6.0 x 4.5 cm uterus with attached unremarkable ovaries (left; 2.0 x

[page 2 of 4]
0.6 x 0.4 cm, right; 1.7 x 0.6 x 0.4 cm). An unremarkable fallopian tube (left 6.7 cm in length with a diameter of 0.5 cm, right; 6.5 cm in length and 0.5 cm in diameter).

The specimen is opened at 3 and 9 o'clock direction. Located within the fundus is a 5.5 x 3.5 x 3.0 cm soft, friable, polypoid mass that involves the anterior wall. Tumor does not invade the myometrium. Tumor does not extend into the lower uterine segment of cervix. The adjacent normal endometrium has a maximum thickness of 0.1 cm. The myometrium has two intramural white firm and whorled nodules from 0.3 x 0.3 x 0.3 cm to 1.2 x 1.0 x 0.9 cm.

SECTION CODE: B1, cervix at 12 o'clock; B2, cervix - 6 o'clock; B3-B9, representative sections of the tumor; B10, tumor with anterior wall; B11, anterior full thickness of the uterus; B12, posterior full thickness of the uterus; B13, two nodules representative sections; B14, left ovary bisected and entirely submitted; B15, left fallopian tube, representative section; B16, right ovary bisected and entirely submitted; B17, right fallopian, representative section. A portion of tumor and normal tissue is submitted for tumor bank.

*FS/DX: POLYPOID MASS WITHOUT GROSS EVIDENCE OF DEEP INVASION.

(C) LEFT PELVIC NODE - Multiple fragments of yellow-pink adipose tissue measuring 9.0 x 7.0 x 1.0 cm in aggregate. Multiple lymph nodes identified with the largest measuring 5.0 x 2.5 x 0.8 cm. The lymph nodes are entirely submitted as follows.

SECTION CODE: C1, four possible lymph nodes; C2, three possible lymph node; C3-C6, one lymph node bisected in each block; C7-C12, one lymph node (largest) serially sectioned.

(D) LEFT COMMON ILIAC SENTINEL LYMPH NODE, COUNT 514 - One piece of pink soft tissue (5.0 x 1.0 x 0.5 cm, one possible lymph node identified measuring 5.0 x 0.5 x 0.5 cm in greatest dimension, serially sectioned and entirely submitted in D1-D3.

(E) LEFT COMMON LYMPH NODE - One piece of pink soft tissue (2.5 x 2.0 x 0.5 cm). One possible lymph node identified measuring 1.4 x 0.6 x 0.5 cm and is bisected and entirely submitted in E.

(F) RIGHT COMMON ILIAC LYMPH NODE - One piece of pink soft tissue (7.0 x 2.0 x 0.4 cm). One possible lymph node identified measuring 3.3 x 1.5 x 0.5 cm and is serially sectioned and entirely submitted in F1-F2.

(G) RIGHT PELVIC LYMPH NODE - A fragment of yellow-pink soft tissue (5.0 x 5.0 x 1.0 cm in aggregate). Multiple lymph nodes identified with the largest measuring 3.2 cm in greatest dimension and entirely submitted as follows.

SECTION CODE: G1-G4, one possible node bisected in each block; G5, G6, one possible node serially sectioned (largest); G7, G8, one possible lymph node serially sectioned; G9, one possible node.

(H) PARAAORTIC LYMPH NODE - A 3.2 x 2.7 x 0.4 cm portion of fibroadipose tissue. The tissue is dissected to reveal six possible lymph nodes ranging from 0.2 x 0.1 x 0.1 cm - 2.7 x 0.7 x 0.3 cm.

SECTION CODE: H1, one possible lymph node; H2, one possible lymph node; H3, one possible lymph node bisected; H4, one possible lymph node serially sectioned; H5, one possible lymph node serially sectioned; H6, one possible lymph node serially sectioned. Entire specimen is submitted.

(I) OMENTAL BIOPSY - A 19.5 x 5.0 x 0.6 cm sheet of finely lobulated adipose tissue. The specimen is serially sectioned to reveal cut surfaces composed of unremarkable finely lobulated adipose tissue. A definite mass is not grossly identified.

SECTION CODE: I-I4, representative sections.

CLINICAL HISTORY

Uterine cancer.

SNOMED CODES

T-83020, M-89503

"Some tests reported here may have been developed and performance characteristics determined specifically cleared or approved by the U.S. Food and Drug Administration."

e tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM #1

[page 3 of 4]
ADDENDUM

This modified report is being issued to report special studies/IHC/Molecular studies.

Addendum completed by

MOLECULAR RESULTS

Endometrial carcinoma, microsatellite instability testing:

Microsatellite-stable tumor (see technical report).

Intact (positive) nuclear expression of MLH1, MSH2, MSH6, and PMS2 by immunohistochemistry.

TECHNICAL REPORT

DNA extracted from microdissected paraffin-embedded tumor (T) in sections from block B5 and non-neoplastic tissue (N) from block B16 was analyzed by a PCR-based method followed by capillary electrophoretic detection. A panel of seven microsatellite markers recommended by the NCI (BAT25, BAT26, BAT40, D2S123, D5S346, D17S250 and TGFBR2) was evaluated to detect changes in the number of microsatellite repeats in tumor as compared to normal tissue. No allelic shift was detected in the tested microsatellite markers.

Immunohistochemistry for MLH1, MSH2, MSH6, and PMS2 was performed using formalin-fixed, paraffin-embedded sections of the endometrial carcinoma.

**This test was developed and its performance determined by cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes.

Technical review completed by

MATERIALS TESTED

Tissue:	Endometrial carcinoma (tumor), ovary (normal)
Block(s):	B16, B5
Collection Date:	
Ordering Clinician:	
Submitting Pathologist:	

Entire report and diagnosis completed by

Start of ADDENDUM #2

[page 4 of 4]
ADDENDUM #2

This modified report is being issued to provide results for additional studies performed for sentinel lymph node (part D).

Addendum completed by

COMMENT

Microscopic examination of H&E stained deeper sections of the sentinel lymph node (left common iliac lymph node, D) demonstrates no evidence of metastatic carcinoma. Pancytokeratin immunohistochemistry was also performed for the sentinel lymph node. These sections demonstrate no evidence of metastatic carcinoma.

The original diagnosis remains unchanged.

Entire report and diagnosis completed

-----END OF REPORT-----

Preliminary: 10/10/12 *LM*

Source: NCI Genomic Data Commons file 52a3d348-611a-4b8b-82ef-061df47e0e1c (TCGA-N9-A4Q3.85013BAC-C695-4E3D-A217-060E35024A40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).